National Lung Screening Trial (NLST) participant 212266 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, no significant abnormalities.
- T1 (day 366): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality).
- T2: No screening result: Not Expected - Death before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T1; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 414, study year T1. Site: main bronchus (ICD-O-3 C34.0), determined from cytology. Primary tumour location: left upper lobe, left main stem bronchus. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Tumour size on pathology: 65 mm. AJCC 6th edition staging: stage IV (best stage, from pathologic TNM); clinical T2 NX MX; pathologic T2 N3 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T2b NX MX; pathologic T2b N3 M1b. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 414 (for ACRIN participants with lung cancer this field holds the diagnosis date).
